Somatic mutation profile of tumor specimen C3L-05313-54 (aliquot CPT0339580002) from CPTAC case C3L-05313, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 55.4 years (20,246 days).
Specimen C3L-05313-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4efab11-cce0-4d82-8a1c-171bc8c6dd84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05313-50 (Buccal Cell Normal), aliquot CPT0339550004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96548ca6-03fa-474b-9d60-18bf97606899

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 19/80 reads (24%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNMT3A | c.976C>A p.R326S | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747448117, COSV53036167; called by muse, mutect2, varscan2
- MYO10 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs1203961371; called by muse, mutect2, varscan2
- PAK6 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753304529, COSV53045598; called by muse, varscan2
- RBBP4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as rs766075227, COSV65132341; called by muse, varscan2
- AADACL3 | c.391del p.H131Tfs*33 | Frame Shift Del (DEL) | VAF 43/106 reads (41%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.1634C>T p.T545I | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FBXO8 | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRABP1 | c.123C>T p.H41= | Silent (SNP) | VAF 75/176 reads (43%) | catalogued as COSV55115888; called by muse, mutect2, varscan2
- DALRD3 | chr3:49020673 A>G | 5'Flank (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- TMEM273 | c.*12C>T | 3'UTR (SNP) | VAF 74/167 reads (44%) | catalogued as rs371134595; called by muse, mutect2, varscan2
- TTC6 | c.357+1625G>A | Intron (SNP) | VAF 60/154 reads (39%) | called by muse, varscan2
